Somatic mutation profile of tumor specimen TCGA-D1-A16J-01A (aliquot TCGA-D1-A16J-01A-11D-A12J-09) from TCGA case TCGA-D1-A16J, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 61.1 years (22,319 days).
Specimen TCGA-D1-A16J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27d79f86-9294-4c2e-857a-c770c4f94c65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16J-10A (Blood Derived Normal), aliquot TCGA-D1-A16J-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e4eeb37-7fb6-4844-87af-3a5f1aa4f2d7

The open-access MAF lists 256 somatic variants for this specimen: 189 protein-altering or splice-affecting, 63 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 165, Silent 63, Nonsense Mutation 15, Intron 4, Frame Shift Del 4, Splice Region 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 52/146 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABHD2 | c.453G>T p.Q151H | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV61775356; called by muse, mutect2, varscan2
- ABI3BP | c.292C>A p.P98T | Missense Mutation (SNP) | VAF 63/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761330735, COSV52544741; called by muse, mutect2, varscan2
- ACTN4 | c.1690G>A p.E564K | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV53148353, COSV99400181; called by muse, mutect2, varscan2
- ADAMTS19 | c.85G>A p.V29I | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs773904041, COSV50770862; called by muse, mutect2, varscan2
- ADGRG4 | c.3803C>A p.T1268N | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54962368; called by muse, mutect2, varscan2
- ADGRV1 | c.7945G>T p.G2649C | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67991043; called by muse, mutect2, varscan2
- AKAP12 | c.4432G>A p.D1478N | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs775450726, COSV53579040; called by muse, mutect2, varscan2
- AMBRA1 | c.1199C>G p.S400C (on ENST00000458649 / NM_001367468.1; = p.S310C on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.343); catalogued as COSV54058859; called by muse, mutect2, varscan2
- ANO2 | c.1552G>A p.D518N (on ENST00000356134 / NM_001278597.3; = p.D522N on NM_001278596.3) | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as COSV59034435; called by muse, mutect2, varscan2
- ARFGEF1 | c.3070G>T p.D1024Y | Missense Mutation (SNP) | VAF 162/505 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51613472; called by muse, mutect2, varscan2
- ARFGEF1 | c.2797C>T p.Q933* | Nonsense Mutation (SNP) | VAF 132/342 reads (39%) | catalogued as COSV51613483, COSV51613615, COSV51619012; called by muse, mutect2, varscan2
- ARFGEF2 | c.1731G>A p.W577* | Nonsense Mutation (SNP) | VAF 62/215 reads (29%) | catalogued as COSV64213884; called by muse, mutect2, varscan2
- ARHGAP25 | c.1424C>T p.S475L (on ENST00000409202 / NM_001007231.3; = p.S467L on NM_014882.3) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV54903659, COSV54905677; called by muse, mutect2, varscan2
- ARL4D | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60721718; called by muse, mutect2, varscan2
- ARMC12 | c.778G>T p.E260* (on ENST00000373866 / NM_001286574.2; = p.E287* on NM_145028.5) | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as COSV55360788; called by muse, mutect2, varscan2
- ATP8A1 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52533057, COSV52542140; called by muse, mutect2, varscan2
- ATRN | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 137/599 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs760560964, COSV53531305; called by muse, mutect2, varscan2
- ATRN | c.3579G>C p.L1193F | Missense Mutation (SNP) | VAF 53/231 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV53531311; called by muse, mutect2, varscan2
- BCL9 | c.147G>C p.Q49H | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.371); catalogued as COSV52347882; called by muse, mutect2, varscan2
- BLK | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs149605952; called by muse, mutect2, varscan2
- BNIPL | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 76/151 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs764413830, COSV54845752; called by muse, mutect2, varscan2
- BRD1 | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53459840; called by muse, mutect2, varscan2
- C20orf194 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 27/306 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.316); catalogued as COSV52699901; called by muse, mutect2
- C2orf16 | c.5383G>A p.E1795K | Missense Mutation (SNP) | VAF 63/189 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as COSV62677188; called by muse, mutect2, varscan2
- CARD18 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 14/286 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.085); catalogued as COSV73233213; called by muse, mutect2
- CBLN4 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV50353675, COSV99290307; called by muse, mutect2, varscan2
- CEP128 | c.2224G>C p.E742Q | Missense Mutation (SNP) | VAF 57/126 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as COSV55384609; called by muse, mutect2, varscan2
- CEP152 | c.3790G>A p.E1264K (on ENST00000380950 / NM_001194998.2; = p.E1208K on NM_014985.4) | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.422); catalogued as COSV57862020; called by muse, mutect2, varscan2
- CLPTM1L | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771252174, COSV57991773; called by muse, mutect2, varscan2
- CNTRL | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 118/387 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53049156; called by muse, mutect2, varscan2
- COL4A4 | c.1209G>A p.M403I | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV61634523; called by muse, mutect2, varscan2
- CPAMD8 | c.2083G>C p.D695H (on ENST00000651564; = p.D648H on NM_015692.5) | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as COSV52237404; called by muse, mutect2, varscan2
- CRB1 | c.3613G>A p.G1205R | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs574742644, CM010803, COSV66332114; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRTC1 | c.1358C>A p.S453Y | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58721294; called by muse, mutect2, varscan2
- CSMD3 | c.7231G>A p.D2411N (on ENST00000297405 / NM_001363185.1; = p.D2307N on NM_052900.3) | Missense Mutation (SNP) | VAF 111/327 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs778257874, COSV52254941; called by muse, mutect2, varscan2
- CTNND2 | c.1537G>T p.E513* | Nonsense Mutation (SNP) | VAF 58/172 reads (34%) | catalogued as COSV58908112, COSV58908709; called by muse, mutect2, varscan2
- CUBN | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 162/315 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.296); catalogued as COSV64701765; called by muse, mutect2, varscan2
- DARS2 | c.841-1G>C p.X281_splice | Splice Site (SNP) | VAF 73/222 reads (33%) | catalogued as COSV53408075; called by muse, mutect2, varscan2
- DBX1 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV57054749; called by muse, mutect2, varscan2
- DCLRE1B | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1487776086, COSV65813319; called by muse, mutect2
- DDX31 | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 102/324 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as rs1160095179, COSV64650679; called by muse, mutect2, varscan2
- DENND4C | c.2905G>A p.G969R (on ENST00000434457 / NM_001330640.2; = p.G920R on NM_017925.7) | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.401); catalogued as rs1002606747, COSV66820082; called by muse, mutect2, varscan2
- DEUP1 | c.199G>C p.E67Q | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751944109, COSV53214642; called by muse, mutect2, varscan2
- DHX57 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 79/216 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.309); catalogued as COSV54888755, COSV99769745; called by muse, mutect2
- DHX57 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 83/232 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV54888781; called by muse, mutect2, varscan2
- DNER | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59171707; called by muse, mutect2, varscan2
- DOCK7 | c.3697C>G p.Q1233E (on ENST00000635253 / NM_001367561.1; = p.Q1202E on NM_033407.3) | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52014943; called by muse, mutect2, varscan2
- DPP4 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 94/303 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62108392; called by muse, mutect2, varscan2
- DSCAML1 | c.5284G>A p.V1762I (on ENST00000321322; = p.V1702I on NM_020693.4) | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.984); catalogued as rs147907435; called by muse, mutect2, varscan2
- DVL2 | c.1519G>A p.D507N | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV50038100; called by muse, mutect2, varscan2
- E2F1 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV55777448; called by muse, mutect2, varscan2
- ELF3 | c.738A>T p.K246N | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as COSV62839416; called by muse, mutect2, varscan2
- EME2 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV51601944; called by muse, mutect2, varscan2
- ENPP6 | c.193C>G p.P65A | Missense Mutation (SNP) | VAF 4/100 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57070217; called by muse, mutect2
- ERBB3 | c.647G>C p.G216A | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.44); catalogued as COSV57246828; called by muse, mutect2, varscan2
- EXPH5 | c.1639G>C p.E547Q | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV56205587; called by muse, mutect2, varscan2
- FARP2 | c.1779C>A p.F593L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV50875824; called by muse, mutect2
- FAT4 | c.9763C>G p.Q3255E | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100627472, COSV58698755; called by muse, mutect2, varscan2
- FAT4 | c.10068G>T p.Q3356H | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58698768; called by muse, mutect2
- FERMT2 | c.843T>G p.D281E | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV58408361; called by muse, mutect2, varscan2
- FGG | c.1036G>C p.D346H | Missense Mutation (SNP) | VAF 92/286 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60196147; called by muse, mutect2, varscan2
- FLNA | c.6640G>A p.V2214M (on ENST00000369850 / NM_001110556.2; = p.V2206M on NM_001456.3) | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61047989; called by muse, mutect2, varscan2
- FRYL | c.2754T>G p.F918L | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV51954865; called by muse, mutect2, varscan2
- FTHL17 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV63267474; called by muse, mutect2, varscan2
- FZD3 | c.1591G>T p.D531Y | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.949); catalogued as COSV53536858; called by muse, mutect2
- G3BP2 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 72/227 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV62977040; called by muse, mutect2, varscan2
- GAL3ST4 | c.784C>G p.P262A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.607); catalogued as COSV57587261; called by muse, mutect2, varscan2
- GALNT5 | c.1573C>T p.P525S | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.754); catalogued as COSV52039528; called by muse, mutect2
- GGA1 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as rs375317914; called by muse, mutect2, varscan2
- GIPR | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.956); catalogued as COSV54425338, COSV99624919; called by muse, mutect2, varscan2
- GLT1D1 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 83/260 reads (32%) | catalogued as rs770732594, COSV55885129; called by muse, mutect2, varscan2
- GPR141 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772202718, COSV57733375; called by muse, mutect2, varscan2
- GPRASP2 | c.2176T>A p.L726I | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59992044; called by muse, mutect2
- GRIN2A | c.3506G>A p.R1169Q | Missense Mutation (SNP) | VAF 45/179 reads (25%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.986); catalogued as rs761399460, COSV58030962; called by muse, mutect2, varscan2
- GRIP1 | c.1781G>C p.R594T (on ENST00000359742 / NM_001379345.1; = p.R542T on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 133/343 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV54033823; called by muse, mutect2, varscan2
- HOOK2 | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV53403193; called by muse, mutect2, varscan2
- IBSP | c.841G>C p.E281Q | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.28); catalogued as COSV56896531; called by muse, mutect2
- IDUA | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs992336192, CM022023, COSV56103464; called by muse, mutect2, varscan2
- IGF1 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV61033719; called by muse, mutect2, varscan2
- INTS13 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV53901989; called by muse, mutect2
- KCNC4 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63926197; called by muse, mutect2, varscan2
- KCNH2 | c.1426G>A p.V476I | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs199472908, CM097436, COSV51133907; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- KCNN3 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV55222156; called by muse, mutect2, varscan2
- KCNQ2 | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 93/346 reads (27%) | SIFT tolerated (0.9); PolyPhen benign (0.011); catalogued as COSV60437035; called by muse, mutect2, varscan2
- KCNU1 | c.3355C>T p.Q1119* | Nonsense Mutation (SNP) | VAF 51/146 reads (35%) | catalogued as COSV67758277; called by muse, mutect2, varscan2
- KCTD7 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.249); catalogued as rs780710316, COSV51877186; called by muse, mutect2, varscan2
- KIF13A | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV52459601, COSV99435531; called by muse, mutect2, varscan2
- KIF21B | c.4268C>T p.S1423L (on ENST00000422435 / NM_001252100.2; = p.S1410L on NM_017596.4) | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs1191391325, COSV59754665; called by muse, mutect2, varscan2
- LDLR | c.2388C>T p.I796= | Splice Region (SNP) | VAF 21/87 reads (24%) | catalogued as rs543852919, COSV52944882; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- LRIG1 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as rs753322104, COSV56244869; called by muse, mutect2, varscan2
- LRP5 | c.3853G>A p.E1285K | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs749297859, COSV53720137; called by muse, mutect2, varscan2
- LRRC37B | c.2372C>T p.S791L | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV58953695; called by muse, mutect2
- LTBP2 | c.3610G>A p.A1204T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as rs574833922, COSV56211390; called by muse, mutect2, varscan2
- MAML2 | c.2510C>T p.S837L | Missense Mutation (SNP) | VAF 195/509 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs749105270, COSV73264242; called by muse, mutect2, varscan2
- MAP4K3 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 143/422 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as COSV55715922; called by muse, mutect2, varscan2
- MARK2 | c.1294G>A p.A432T (on ENST00000402010 / NM_001039469.2; = p.A431T on NM_004954.5) | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs538928060, COSV59286310; called by muse, mutect2, varscan2
- MCCC1 | c.2014G>T p.D672Y | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55610400, COSV99659528; called by muse, mutect2, varscan2
- MGAM | c.389G>A p.C130Y | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71885784; called by muse, mutect2, varscan2
- MRPL49 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 76/230 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.583); catalogued as rs539335985, COSV53695611; called by muse, mutect2, varscan2
- MUC16 | c.38162C>T p.S12721F | Missense Mutation (SNP) | VAF 153/457 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV67480636; called by muse, mutect2, varscan2
- MUC16 | c.24751G>A p.D8251N | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV67480639; called by muse, mutect2, varscan2
- MUC16 | c.15536A>G p.N5179S | Missense Mutation (SNP) | VAF 108/301 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV67480645; called by muse, mutect2, varscan2
- MYH10 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 104/312 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1291237756, COSV52606499; called by muse, mutect2, varscan2
- MYH3 | c.1946C>G p.S649C | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV56867872; called by muse, mutect2, varscan2
- MYOM3 | c.1835G>A p.R612K | Missense Mutation (SNP) | VAF 96/154 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58397423; called by muse, mutect2, varscan2
- NAA15 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 78/215 reads (36%) | catalogued as COSV56721380; called by muse, mutect2, varscan2
- NCOA2 | c.4042C>T p.Q1348* | Nonsense Mutation (SNP) | VAF 66/178 reads (37%) | catalogued as COSV51218804; called by muse, mutect2, varscan2
- NEU2 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201184759, COSV52093470; called by muse, mutect2, varscan2
- NIN | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.385); catalogued as COSV55399493; called by muse, mutect2, varscan2
- NLGN3 | c.1705G>A p.D569N (on ENST00000358741 / NM_181303.2; = p.D549N on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.393); catalogued as COSV62444538; called by muse, mutect2, varscan2
- NOS1AP | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV62637908; called by muse, mutect2, varscan2
- NOS1AP | c.611G>C p.G204A | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV62637922; called by muse, mutect2, varscan2
- NOX1 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 34/113 reads (30%) | catalogued as COSV54195830; called by muse, mutect2, varscan2
- OLFML2A | c.346C>T p.L116F | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.999); catalogued as COSV59161568; called by muse, mutect2
- OR6C3 | c.809G>C p.G270A | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.816); catalogued as rs376754458, COSV65571570; called by muse, mutect2
- OTOP2 | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV58882910; called by muse, mutect2, varscan2
- PAIP1 | c.1324G>A p.D442N | Missense Mutation (SNP) | VAF 92/314 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as COSV59086747; called by muse, mutect2, varscan2
- PARPBP | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 108/316 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1233829242, COSV59675252; called by muse, mutect2, varscan2
- PARS2 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1258704872, COSV64883773; called by muse, mutect2, varscan2
- PASK | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs563062107, COSV52148560; called by muse, mutect2, varscan2
- PCDHA4 | c.1526C>T p.S509L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs538251882, COSV63544192; called by muse, mutect2, varscan2
- PCDHGA10 | c.1599G>C p.Q533H | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.049); catalogued as COSV53926116, COSV53993548; called by muse, mutect2, varscan2
- PCDHGA2 | c.1793C>T p.S598L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs267600445, COSV53893809; called by muse, mutect2, varscan2
- PCSK5 | c.2609G>A p.G870E | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV65089911, COSV65093064; called by muse, mutect2
- PDCL3 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs750616995, COSV51809826; called by muse, varscan2
- PHF14 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 22/507 reads (4%) | catalogued as COSV68856426; called by muse, mutect2
- PHKB | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.08); catalogued as COSV54528590; called by muse, mutect2, varscan2
- PHRF1 | c.3829G>A p.D1277N (on ENST00000264555 / NM_001286581.2; = p.D1276N on NM_020901.4) | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs1017678288, COSV52753089, COSV52759443; called by muse, mutect2, varscan2
- PKD1 | c.4808C>T p.S1603F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99238985; called by muse, mutect2
- PKD1 | c.3323C>G p.S1108C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1200048253, COSV51921352, COSV99238209; called by muse, mutect2
- PLCG2 | c.870C>T p.F290= | Splice Region (SNP) | VAF 5/67 reads (7%) | catalogued as rs1428474775, COSV63873134; ClinVar: likely benign; called by muse, mutect2
- POR | c.93G>C p.M31I | Missense Mutation (SNP) | VAF 80/233 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67517721; called by muse, mutect2, varscan2
- PPCS | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 67/168 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.571); catalogued as rs756903119, COSV65333767; called by muse, mutect2, varscan2
- PPP3R1 | c.296A>G p.Y99C | Missense Mutation (SNP) | VAF 94/270 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52247903; called by muse, mutect2, varscan2
- PRORP | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.117); catalogued as rs1374024878, COSV51621229; called by muse, mutect2, varscan2
- PRORP | c.674G>C p.R225T | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV51621243; called by muse, mutect2, varscan2
- PTPRS | c.4038C>A p.F1346L | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV53629565; called by muse, mutect2
- RALGAPB | c.1222A>G p.K408E | Missense Mutation (SNP) | VAF 227/442 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV53437292; called by muse, mutect2, varscan2
- RANBP2 | c.2504C>T p.S835L | Missense Mutation (SNP) | VAF 157/531 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV51705238; called by muse, mutect2
- RAP2C | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV61683566; called by muse, mutect2
- RHPN2 | c.912C>G p.F304L | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV54282191; called by muse, mutect2
- RNF123 | c.343-1G>A p.X115_splice | Splice Site (SNP) | VAF 50/144 reads (35%) | catalogued as COSV100570690, COSV59690415; called by muse, mutect2, varscan2
- RYR3 | c.10167C>G p.I3389M (on ENST00000389232; = p.I3390M on NM_001036.6) | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1329128295, COSV66801670; called by muse, mutect2, varscan2
- SALL2 | c.72C>T p.N24= | Splice Region (SNP) | VAF 34/96 reads (35%) | catalogued as COSV58104829; called by muse, mutect2, varscan2
- SCN9A | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 83/205 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV57617783; called by muse, mutect2, varscan2
- SEBOX | c.368C>T p.S123L | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV52647636; called by muse, mutect2, varscan2
- SETD5 | c.1058C>A p.S353* | Nonsense Mutation (SNP) | VAF 86/285 reads (30%) | catalogued as COSV56714826; called by muse, mutect2, varscan2
- SGSM2 | c.2601G>A p.M867I (on ENST00000426855 / NM_001098509.2; = p.M912I on NM_014853.3) | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV52160110; called by muse, mutect2, varscan2
- SIPA1L2 | c.1872G>A p.M624I | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1337408820, COSV53395356; called by muse, mutect2
- SIPA1L2 | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV53395367, COSV99476893; called by muse, mutect2, varscan2
- SIRPG | c.783G>A p.M261I | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV53808957; called by muse, mutect2, varscan2
- SLC11A2 | c.1319G>A p.R440Q (on ENST00000394904 / NM_001379455.1; = p.R411Q on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/171 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs759374719, COSV50373295; called by muse, mutect2, varscan2
- SLC19A1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV60756279; called by muse, varscan2
- SLC9C1 | c.52G>C p.V18L | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV59890731, COSV99997672; called by muse, mutect2, varscan2
- SMCHD1 | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV55263738; called by muse, mutect2, varscan2
- STXBP5L | c.2413A>G p.T805A | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV56525181; called by muse, mutect2, varscan2
- TBX10 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.229); catalogued as COSV56876129; called by muse, mutect2, varscan2
- TCHH | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 115/313 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.012); catalogued as COSV64275171, COSV64276373; called by muse, mutect2, varscan2
- TENM1 | c.6727G>A p.G2243S | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV64438246; called by muse, mutect2
- TMEM225 | c.212C>T p.T71M | Missense Mutation (SNP) | VAF 73/230 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs370834352; called by muse, mutect2, varscan2
- TMPRSS7 | c.2522C>T p.S841F (on ENST00000452346; = p.S715F on NM_001042575.2) | Missense Mutation (SNP) | VAF 107/358 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as rs751339070, COSV69981978; called by muse, mutect2, varscan2
- TTC14 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV56013219, COSV56013786; called by muse, mutect2, varscan2
- TTN | c.56414G>A p.R18805H (on ENST00000591111; = p.R11381H on NM_003319.4) | Missense Mutation (SNP) | VAF 71/183 reads (39%) | PolyPhen probably damaging (0.998); catalogued as rs368278158; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TULP4 | c.2605G>A p.D869N | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as rs1159407392, COSV65578605; called by muse, mutect2, varscan2
- UBR4 | c.6289G>A p.E2097K | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV64385642; called by muse, mutect2, varscan2
- USF3 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 205/548 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57075457; called by muse, mutect2, varscan2
- USP29 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 60/153 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.051); catalogued as COSV54144739, COSV54145537; called by muse, mutect2, varscan2
- USP8 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.994); catalogued as COSV56166359; called by muse, mutect2
- VSIG10 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.209); catalogued as COSV63654046; called by muse, varscan2
- WDFY3 | c.8430C>G p.F2810L | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV55708889; called by muse, mutect2, varscan2
- WNK3 | c.2233C>T p.Q745* | Nonsense Mutation (SNP) | VAF 10/290 reads (3%) | catalogued as COSV63615133; called by muse, mutect2
- WWC1 | c.1376C>A p.S459* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as rs772962820, COSV54655152; called by muse, mutect2, varscan2
- ZAN | c.6220G>A p.D2074N | Missense Mutation (SNP) | VAF 105/268 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV61812410; called by muse, mutect2, varscan2
- ZFP37 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 8/189 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV65287926; called by muse, mutect2
- ZFR | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 17/526 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs917778909, COSV54055627; called by muse, mutect2
- ZNF140 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60579703; called by muse, mutect2, varscan2
- ZNF181 | c.768G>A p.W256* | Nonsense Mutation (SNP) | VAF 38/165 reads (23%) | catalogued as rs1293396461, COSV67627031; called by muse, mutect2, varscan2
- ZNF195 | c.865G>A p.E289K (on ENST00000399602 / NM_001130520.3; = p.E217K on NM_007152.5) | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.043); catalogued as COSV50005681; called by muse, mutect2, varscan2
- ZNF407 | c.1846C>G p.L616V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV55259237, COSV55262320; called by muse, mutect2, varscan2
- ZNF443 | c.53G>T p.W18L | Missense Mutation (SNP) | VAF 58/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56893017; called by muse, mutect2, varscan2
- ZNF783 | c.44A>G p.H15R | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1180299374, COSV65186210; called by muse, mutect2
- ZUP1 | c.173T>G p.L58R | Missense Mutation (SNP) | VAF 170/535 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1390736333, COSV63944589; called by muse, mutect2, varscan2
- ACBD7 | c.250del p.E84Kfs*16 | Frame Shift Del (DEL) | VAF 22/200 reads (11%) | called by pindel, varscan2
- BCORL1 | c.3001del p.Q1001Rfs*49 | Frame Shift Del (DEL) | VAF 31/104 reads (30%) | called by mutect2, pindel, varscan2
- BCR | c.1303G>T p.G435* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- FAS | c.504del p.G169Dfs*18 | Frame Shift Del (DEL) | VAF 130/321 reads (40%) | called by mutect2, pindel, varscan2
- KIAA0586 | c.1102_1109del p.E368Ffs*3 (on ENST00000619416 / NM_001244190.2; = p.E383Ffs*3 on NM_014749.5) | Frame Shift Del (DEL) | VAF 27/126 reads (21%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2240G>A p.R747K | Missense Mutation (SNP) | VAF 61/205 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AFTPH | c.1959G>A p.E653= | Silent (SNP) | VAF 75/201 reads (37%) | catalogued as rs757073333, COSV53220227; called by muse, mutect2, varscan2
- ATP2B2 | c.3375G>A p.R1125= (on ENST00000352432; = p.R1091= on NM_001683.5) | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV59503324; called by muse, mutect2, varscan2
- ATP6V1A | c.771A>T p.T257= | Silent (SNP) | VAF 81/261 reads (31%) | catalogued as COSV56363512; called by muse, mutect2, varscan2
- BNIPL | c.105G>A p.L35= | Silent (SNP) | VAF 150/413 reads (36%) | catalogued as COSV54848056; called by muse, mutect2, varscan2
- C5orf15 | c.69C>T p.I23= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs747208047, COSV51548789; called by muse, mutect2, varscan2
- C9orf50 | c.633G>A p.T211= | Silent (SNP) | VAF 70/186 reads (38%) | catalogued as COSV65252754; called by muse, mutect2, varscan2
- CD300LG | c.696C>T p.L232= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV53224980; called by muse, mutect2, varscan2
- CELSR1 | c.3063T>A p.I1021= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV53095293; called by muse, mutect2, varscan2
- CFAP94 | c.402G>A p.K134= (on ENST00000320267 / NM_001352064.2; = p.K140= on NM_018272.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 143/404 reads (35%) | catalogued as COSV57234836; called by muse, mutect2, varscan2
- CNTROB | c.2493G>A p.L831= | Silent (SNP) | VAF 68/201 reads (34%) | catalogued as rs1322925256, COSV66608837; called by muse, mutect2, varscan2
- CORIN | c.2637C>A p.I879= | Silent (SNP) | VAF 70/180 reads (39%) | catalogued as COSV56695682; called by muse, mutect2, varscan2
- CPA1 | c.231C>A p.I77= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV50572662; called by muse, mutect2, varscan2
- CSNK1E | c.762C>T p.F254= | Silent (SNP) | VAF 69/178 reads (39%) | catalogued as rs1223607526, COSV63291698; called by muse, mutect2, varscan2
- CXCR6 | c.250C>T p.L84= | Silent (SNP) | VAF 85/244 reads (35%) | catalogued as COSV56117956; called by muse, mutect2, varscan2
- DIAPH3 | c.2880A>C p.A960= (on ENST00000400324 / NM_001042517.2; = p.A697= on NM_030932.3) | Silent (SNP) | VAF 105/295 reads (36%) | catalogued as COSV57375664; called by muse, mutect2, varscan2
- DPM3 | c.126C>G p.P42= (on ENST00000341298; = p.P72= on NM_018973.3) | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100310353, COSV57597533; called by muse, mutect2, varscan2
- ESPL1 | c.3126T>C p.N1042= | Silent (SNP) | VAF 88/217 reads (41%) | catalogued as COSV57761149; called by muse, mutect2, varscan2
- FBLN1 | c.945C>T p.I315= | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as rs1288087442, COSV53051206; called by muse, mutect2, varscan2
- FGG | c.783G>A p.L261= | Silent (SNP) | VAF 64/196 reads (33%) | catalogued as COSV60195574, COSV60196155; called by muse, mutect2, varscan2
- FOXC2 | c.84G>A p.A28= | Silent (SNP) | VAF 13/15 reads (87%) | catalogued as rs748779213, COSV57444990; called by muse, mutect2, varscan2
- GLB1L3 | c.1950G>A p.K650= | Silent (SNP) | VAF 98/231 reads (42%) | catalogued as COSV68393166; called by muse, mutect2, varscan2
- H1-5 | c.444G>A p.A148= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV58900863; called by muse, mutect2, varscan2
- HAVCR1 | c.576G>A p.T192= | Silent (SNP) | VAF 138/439 reads (31%) | catalogued as rs113007512, COSV59401773; called by muse, mutect2, varscan2
- IGF1R | c.3135T>A p.I1045= | Silent (SNP) | VAF 84/228 reads (37%) | catalogued as COSV51332014; called by muse, mutect2
- IGSF11 | c.390C>T p.G130= (on ENST00000393775 / NM_001015887.3; = p.G129= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as COSV61174238; called by muse, mutect2, varscan2
- IRS4 | c.1992G>A p.T664= | Silent (SNP) | VAF 124/421 reads (29%) | catalogued as rs765352679, COSV64532622; called by muse, mutect2, varscan2
- ITGAX | c.2430C>T p.D810= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as rs751181843, COSV51648854; called by muse, mutect2, varscan2
- ITPRID1 | c.657G>A p.L219= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as rs768474435, COSV60076739, COSV60079028; called by muse, mutect2, varscan2
- KLHL22 | c.1167C>T p.H389= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs768193484, COSV61022092; called by muse, mutect2, varscan2
- LHX8 | c.792G>A p.L264= | Silent (SNP) | VAF 115/333 reads (35%) | catalogued as COSV53958432; called by muse, mutect2, varscan2
- MCAM | c.1119C>T p.L373= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as COSV50649129; called by muse, mutect2, varscan2
- MIEF1 | c.1092C>G p.L364= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV57479938; called by muse, mutect2, varscan2
- NAA16 | c.597G>A p.V199= | Silent (SNP) | VAF 96/250 reads (38%) | catalogued as COSV65065132, COSV65065952; called by muse, mutect2, varscan2
- NCBP3 | c.1224G>A p.L408= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as COSV50109178; called by muse, mutect2, varscan2
- NMBR | c.243C>T p.F81= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV57802424; called by muse, mutect2, varscan2
- OPTN | c.813T>C p.R271= | Silent (SNP) | VAF 63/217 reads (29%) | catalogued as COSV53812112; called by muse, mutect2, varscan2
- OR13F1 | c.735G>A p.L245= | Silent (SNP) | VAF 63/160 reads (39%) | catalogued as COSV58251789, COSV58252188; called by muse, mutect2, varscan2
- OR51F2 | c.120C>T p.A40= | Silent (SNP) | VAF 18/270 reads (7%) | catalogued as rs747026783, COSV59065505; called by muse, mutect2
- PATZ1 | c.606C>T p.I202= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs753176411; called by muse, mutect2
- PCDHB3 | c.2157G>A p.A719= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs782558033, COSV50570325; called by muse, mutect2, varscan2
- PCNX2 | c.3612C>T p.L1204= | Silent (SNP) | VAF 56/160 reads (35%) | catalogued as COSV50839430; called by muse, mutect2, varscan2
- PKD2L2 | c.1416C>T p.I472= | Silent (SNP) | VAF 304/905 reads (34%) | catalogued as COSV51799747; called by muse, mutect2, varscan2
- PLCD1 | c.642C>T p.I214= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs577077909, COSV52183854; called by muse, mutect2, varscan2
- POGZ | c.2361C>A p.A787= | Silent (SNP) | VAF 76/201 reads (38%) | catalogued as COSV55039354; called by muse, mutect2, varscan2
- POLD1 | c.723C>T p.F241= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs764364345, COSV70956464; ClinVar: likely benign; called by muse, mutect2, varscan2
- PON1 | c.801C>T p.L267= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as rs766399556, COSV55933218; called by muse, mutect2, varscan2
- PRORP | c.177G>A p.T59= | Silent (SNP) | VAF 45/151 reads (30%) | catalogued as COSV51621210; called by muse, mutect2, varscan2
- PRR5 | c.495G>A p.A165= (on ENST00000336985 / NM_181333.4; = p.A156= on NM_015366.4) | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs769702913, COSV50062199; called by muse, mutect2, varscan2
- PSMF1 | c.351G>A p.L117= | Silent (SNP) | VAF 38/190 reads (20%) | catalogued as COSV55675140; called by muse, mutect2, varscan2
- RIPOR3 | c.2307G>T p.L769= | Silent (SNP) | VAF 4/80 reads (5%) | catalogued as COSV50395770; called by muse, mutect2
- RPP38 | c.397C>T p.L133= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV65382757; called by muse, mutect2, varscan2
- SEC24A | c.1797G>A p.L599= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV59748651; called by muse, mutect2, varscan2
- SKOR1 | c.2658C>T p.L886= | Silent (SNP) | VAF 44/140 reads (31%) | catalogued as rs1167651197, COSV58248343; called by muse, varscan2
- SLC35A2 | c.253C>T p.L85= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as rs782113844, COSV55945846; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC35F3 | c.645C>T p.I215= (on ENST00000366617 / NM_001300845.1; = p.I284= on NM_173508.4) | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs774600669, COSV64020762; called by muse, mutect2, varscan2
- TAGLN3 | c.381G>A p.R127= | Silent (SNP) | VAF 6/152 reads (4%) | catalogued as COSV56328757; called by muse, mutect2
- TIGD7 | c.1512G>A p.L504= | Silent (SNP) | VAF 134/264 reads (51%) | catalogued as COSV51916470; called by muse, mutect2, varscan2
- TUBA3E | c.147C>T p.F49= | Silent (SNP) | VAF 86/213 reads (40%) | catalogued as COSV57270723; called by muse, mutect2, varscan2
- UPF1 | c.1524G>A p.G508= (on ENST00000599848 / NM_001297549.2; = p.G497= on NM_002911.4) | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV53199300; called by muse, mutect2, varscan2
- WWC1 | c.3294C>T p.F1098= | Silent (SNP) | VAF 14/210 reads (7%) | catalogued as rs767462423, COSV54649792; called by muse, mutect2
- ZMYND15 | c.336G>A p.G112= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV52643492; called by muse, mutect2, varscan2
- ZNF883 | c.486C>T p.F162= | Silent (SNP) | VAF 140/390 reads (36%) | catalogued as COSV71309085; called by muse, mutect2, varscan2
- ZXDB | c.1290C>T p.G430= | Silent (SNP) | VAF 65/188 reads (35%) | catalogued as COSV66493158; called by muse, mutect2, varscan2
- EML2 | c.21-139G>A | Intron (SNP) | VAF 12/41 reads (29%) | catalogued as COSV55601955; called by muse, mutect2, varscan2
- FAM86C1P | n.183-1600C>G | Intron (SNP) | VAF 14/350 reads (4%) | catalogued as COSV100660804; called by muse, mutect2
- RBM44 | c.-98-2613G>T | Intron (SNP) | VAF 11/41 reads (27%) | catalogued as COSV57631909; called by muse, mutect2, varscan2
- SGCZ | c.40-298519A>T | Intron (SNP) | VAF 34/111 reads (31%) | catalogued as COSV63009543; called by muse, mutect2, varscan2
